Somatic mutation profile of tumor specimen TCGA-AK-3430-01A (aliquot TCGA-AK-3430-01A-01D-1251-10) from TCGA case TCGA-AK-3430, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.9 years (22,612 days).
Specimen TCGA-AK-3430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a6db528-0108-4e19-a658-2ef9f233393a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3430-10A (Blood Derived Normal), aliquot TCGA-AK-3430-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2977e0f7-27b0-4cf7-ae8c-276f5ae49ccf

The open-access MAF lists 75 somatic variants for this specimen: 62 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 9, Splice Site 6, Nonsense Mutation 5, Frame Shift Ins 4, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMCX5-GPRASP2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV63437129; called by muse, mutect2, varscan2
- BCO2 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as COSV63062564; called by muse, mutect2, varscan2
- CDHR1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV60559681; called by muse, mutect2, varscan2
- CFAP74 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV54564782, COSV54573578; called by muse, mutect2, varscan2
- CHD7 | c.5459G>A p.R1820Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs372644599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1910G>A p.W637* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV62147847; called by muse, mutect2, varscan2
- DHX15 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 80/221 reads (36%) | catalogued as COSV61025738; called by muse, mutect2, varscan2
- DHX15 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV61025745; called by muse, mutect2, varscan2
- DRGX | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV65135808; called by mutect2, varscan2
- EGF | c.2609-1G>T p.X870_splice | Splice Site (SNP) | VAF 88/239 reads (37%) | catalogued as COSV54475864; called by muse, mutect2, varscan2
- EGFL6 | c.1069A>T p.I357L | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV63632893; called by muse, mutect2, varscan2
- EXOC6 | c.639A>C p.K213N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV53319395; called by muse, mutect2, varscan2
- FBN1 | c.4277G>T p.G1426V | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57309938; called by muse, mutect2, varscan2
- FREM2 | c.8863A>G p.K2955E | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV54829356; called by muse, mutect2, varscan2
- GAB4 | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68753050, COSV68754617; called by muse, mutect2, varscan2
- HAP1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782415076, COSV57877457; called by muse, mutect2, varscan2
- HYOU1 | c.2933G>T p.G978V | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV68215173; called by muse, mutect2, varscan2
- ITGB6 | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs143914557; called by muse, mutect2
- JMY | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as rs754674187, COSV68659430; called by muse, mutect2, varscan2
- KDM5C | c.3460del p.E1154Nfs*110 | Frame Shift Del (DEL) | VAF 74/130 reads (57%) | catalogued as COSV64764320; called by pindel, varscan2
- KIR3DL3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52545631, COSV99399929; called by muse, mutect2, varscan2
- KMT2D | c.2622C>A p.C874* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV56413099; called by muse, mutect2, varscan2
- LAMTOR2 | c.152A>C p.N51T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV64145030; called by muse, mutect2, varscan2
- LONP1 | c.1553T>A p.I518N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62260677; called by muse, varscan2
- LONRF1 | c.1501A>C p.N501H | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV68035968; called by muse, mutect2, varscan2
- LRP4 | c.3298A>C p.S1100R | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV66134084; called by muse, mutect2
- MSR1 | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs993646387, COSV50506976; called by muse, mutect2, varscan2
- NBPF1 | c.685A>C p.I229L | Missense Mutation (SNP) | VAF 128/441 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV67426823; called by muse, mutect2, varscan2
- NDNF | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 140/410 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65632641; called by muse, varscan2
- ODR4 | c.341C>A p.A114D | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV55215678; called by muse, mutect2
- OR10G4 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 45/160 reads (28%) | catalogued as rs756484443, COSV57976701; called by muse, mutect2, varscan2
- PDE1B | c.940A>T p.N314Y | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54489687; called by muse, mutect2, varscan2
- PPARGC1B | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV58526392; called by muse, mutect2, varscan2
- PRKD1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as COSV59560008; called by muse, mutect2, varscan2
- PTPN12 | c.1026-1G>A p.X342_splice | Splice Site (SNP) | VAF 46/124 reads (37%) | catalogued as COSV50354284; called by muse, mutect2, varscan2
- PTPRC | c.3607G>T p.A1203S | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs779568827, COSV61406827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV57926505; called by muse, mutect2, varscan2
- RAB39B | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV65624364; called by muse, mutect2, varscan2
- RASSF9 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 121/271 reads (45%) | catalogued as COSV63432621; called by muse, mutect2, varscan2
- SGIP1 | c.1177del p.Y393Tfs*2 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | catalogued as COSV52781124; called by mutect2, pindel, varscan2
- SGSM1 | c.1926A>C p.E642D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV68508825; called by muse, mutect2, varscan2
- SHROOM1 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV60580541; called by muse, mutect2, varscan2
- SLX4IP | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV57944243; called by muse, mutect2, varscan2
- TDRD5 | c.1975G>C p.V659L | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV54239164; called by muse, mutect2, varscan2
- TMPRSS15 | c.1171+1G>T p.X391_splice | Splice Site (SNP) | VAF 37/58 reads (64%) | catalogued as COSV53035192; called by muse, mutect2, varscan2
- TPP2 | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as COSV65751106; called by muse, mutect2, varscan2
- UBLCP1 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.521); catalogued as COSV57142618; called by muse, mutect2, varscan2
- UBR4 | c.3131G>T p.R1044L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64383152, COSV64395403; called by muse, mutect2, varscan2
- USP34 | c.44-1G>C p.X15_splice | Splice Site (SNP) | VAF 16/330 reads (5%) | catalogued as COSV67658553; called by muse, mutect2
- WDR77 | c.302-2A>T p.X101_splice | Splice Site (SNP) | VAF 38/79 reads (48%) | catalogued as COSV52384625; called by muse, mutect2, varscan2
- DNAH9 | c.8326del p.L2776Ffs*2 | Frame Shift Del (DEL) | VAF 80/228 reads (35%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.410del p.T137Nfs*10 | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | called by mutect2, pindel, varscan2
- KIF22 | c.638del p.K213Sfs*22 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, varscan2
- MTMR4 | c.1520_1521dup p.G508Tfs*118 | Frame Shift Ins (INS) | VAF 34/81 reads (42%) | called by mutect2, pindel
- PBRM1 | c.347del p.F116Sfs*58 | Frame Shift Del (DEL) | VAF 145/275 reads (53%) | called by mutect2, pindel, varscan2
- POLD3 | c.947del p.N316Tfs*2 | Frame Shift Del (DEL) | VAF 65/163 reads (40%) | called by mutect2, pindel, varscan2
- SLCO2B1 | c.324del p.F108Lfs*10 | Frame Shift Del (DEL) | VAF 124/278 reads (45%) | called by mutect2, pindel, varscan2
- TMEM145 | c.928_929dup p.Y311Rfs*58 | Frame Shift Ins (INS) | VAF 21/120 reads (18%) | called by mutect2, pindel, varscan2
- USH2A | c.14279dup p.P4761Afs*19 | Frame Shift Ins (INS) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- ZCCHC17 | c.565-12_572del p.X189_splice | Splice Site (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- ZNF343 | c.1315del p.C439Afs*172 | Frame Shift Del (DEL) | VAF 50/130 reads (38%) | called by mutect2, pindel, varscan2
- ZNF548 | c.934_935insT p.R312Mfs*15 | Frame Shift Ins (INS) | VAF 53/132 reads (40%) | called by mutect2, pindel, varscan2
- CD180 | c.1264C>T p.L422= | Silent (SNP) | VAF 146/370 reads (39%) | catalogued as COSV56516921; called by muse, mutect2, varscan2
- CFAP52 | c.717G>A p.L239= | Silent (SNP) | VAF 15/343 reads (4%) | catalogued as COSV55343005; called by muse, mutect2
- CYTH2 | c.676C>T p.L226= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57308752; called by muse, varscan2
- EBF1 | c.711T>C p.N237= | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as rs1374080544, COSV58168351; called by muse, mutect2, varscan2
- IL6 | c.573T>G p.T191= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV51732293; called by muse, mutect2
- ITSN2 | c.3489T>C p.D1163= | Silent (SNP) | VAF 73/202 reads (36%) | catalogued as rs1173730766, COSV61943936; called by muse, mutect2, varscan2
- SLC17A3 | c.936T>C p.N312= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV57759476; called by muse, mutect2, varscan2
- SYBU | c.1365C>T p.D455= (on ENST00000276646 / NM_001099754.2; = p.D454= on NM_017786.6) | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as rs1483030589, COSV52614448; called by muse, mutect2, varscan2
- ZFP91 | c.1050A>G p.G350= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV60157298; called by muse, mutect2, varscan2
- ZMYND11 | c.10T>C p.L4= | Silent (SNP) | VAF 59/148 reads (40%) | catalogued as COSV59076460; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37168839 T>C | 3'Flank (SNP) | VAF 170/456 reads (37%) | catalogued as COSV57052744; called by mutect2, varscan2
- STON2 | c.2784+28C>T | Intron (SNP) | VAF 27/100 reads (27%) | catalogued as COSV50842444; called by muse, mutect2, varscan2
- STON2 | c.2784+27G>A | Intron (SNP) | VAF 27/100 reads (27%) | catalogued as COSV50842454; called by muse, mutect2, varscan2
